Gene-level copy-number profile of tumor specimen TCGA-VF-A8AD-01A from TCGA case TCGA-VF-A8AD, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 37.0 years (13,499 days).
Specimen TCGA-VF-A8AD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.9e8c4159-9108-4cab-8029-4059a447d819.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VF-A8AD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6c0892dc-358e-4e2c-9ded-cbddecfc15ab

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 163; copy number 2: 22,448; copy number 3: 24,034; copy number 4: 11,669; copy number 5: 35; copy number 6: 287; copy number 8: 724; copy number 9: 81; copy number 11: 134; copy number 13: 239.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VF-A8AD-01A-11D-A434-01): tumor purity 0.43, ploidy 2.92, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,178 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:13,977,166–26,756,223, 134 genes, copy number 11 (broad region; genes not listed).
- chr11:83,455,012–85,627,922, 1 gene, copy number 13 (within-gene range 3–13): DLG2.
- chr11:84,545,131–95,041,571, 238 genes, copy number 13 (broad region; genes not listed).
- chr12:66,767–31,993,107, 805 genes, copy number 8–9 (within-gene range 4–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 163. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
